Somatic mutation profile of tumor specimen 0DFBLO from CCDI case PBBSAI, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary carcinoma, NOS; Tissue or organ of origin: Thyroid gland; Age at diagnosis: 13.8 years (5,051 days).
Specimen 0DFBLO: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 92ee88d5-e92a-4549-8eb6-7e485fe26638.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DFBLA (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e580729b-a7a3-48bb-b0d9-a451da0bbd83

The open-access MAF lists 15 somatic variants for this specimen: 9 protein-altering or splice-affecting, 4 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Silent 4, 5'UTR 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANK2 | c.7096G>A p.D2366N | Missense Mutation (SNP) | VAF 77/584 reads (13%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.117); catalogued as COSV52156045; called by muse, mutect2, varscan2
- BBS9 | c.190C>G p.Q64E | Missense Mutation (SNP) | VAF 70/714 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.026); catalogued as rs769256027, CM111654, COSV54157315; called by muse, mutect2, varscan2
- CDH10 | c.2131C>T p.R711W | Missense Mutation (SNP) | VAF 22/713 reads (3%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.953); catalogued as rs1299821656, COSV52574699, COSV52578909; called by muse, mutect2
- CTNNB1 | c.1339C>T p.L447F | Missense Mutation (SNP) | VAF 72/609 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as rs769363745; called by muse, mutect2, varscan2
- C17orf80 | c.843C>G p.S281R | Missense Mutation (SNP) | VAF 25/776 reads (3%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2
- COMP | c.454G>C p.E152Q | Missense Mutation (SNP) | VAF 144/1082 reads (13%) | SIFT tolerated (0.51); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- MAP1A | c.37G>C p.E13Q | Missense Mutation (SNP) | VAF 93/723 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MPHOSPH9 | c.2652A>G p.I884M | Missense Mutation (SNP) | VAF 24/934 reads (3%) | SIFT tolerated (0.12); PolyPhen benign (0.06); called by muse, mutect2
- SHANK2 | c.2971G>C p.E991Q | Missense Mutation (SNP) | VAF 132/972 reads (14%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- ALOX12B | c.672C>T p.R224= | Silent (SNP) | VAF 23/786 reads (3%) | called by muse, mutect2
- ANKRD18B | c.726T>C p.C242= | Silent (SNP) | VAF 46/780 reads (6%) | called by muse, mutect2
- RP1 | c.5361T>C p.H1787= | Silent (SNP) | VAF 71/388 reads (18%) | called by muse, mutect2, varscan2
- SPSB3 | c.939G>A p.L313= | Silent (SNP) | VAF 44/267 reads (16%) | catalogued as rs780242185; called by muse, mutect2, varscan2
- BBOF1 | c.*81A>T | 3'UTR (SNP) | VAF 26/803 reads (3%) | called by muse, mutect2
- RMI1 | c.-9T>A | 5'UTR (SNP) | VAF 20/155 reads (13%) | called by muse, varscan2
